Somatic mutation profile of tumor specimen TCGA-CN-5363-01A (aliquot TCGA-CN-5363-01A-01D-1434-08) from TCGA case TCGA-CN-5363, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 48.3 years (17,635 days).
Specimen TCGA-CN-5363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9899cb3-f05a-454f-b031-4da50d2587a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5363-10A (Blood Derived Normal), aliquot TCGA-CN-5363-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b87efc1-2679-4aec-889d-7a748d67ebee

The open-access MAF lists 205 somatic variants for this specimen: 142 protein-altering or splice-affecting, 57 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 57, Nonsense Mutation 6, Frame Shift Del 6, Splice Site 6, 3'UTR 3, In Frame Del 2, RNA 2, Translation Start Site 1, Nonstop Mutation 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GJA8 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 61/279 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1114167310, COSV53787950; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC126283.2 | c.1416G>C p.W472C | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101144733; called by muse, mutect2, varscan2
- ADAD1 | c.1481C>A p.T494N | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56644767, COSV99636299; called by muse, mutect2, varscan2
- AFTPH | c.1447G>T p.D483Y | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99481238; called by muse, mutect2, varscan2
- AJAP1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100982044; called by muse, mutect2, varscan2
- ANKLE2 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100514371; called by muse, mutect2, varscan2
- AP3B1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs149521661; called by muse, varscan2
- APBA2 | c.1251+1G>T p.X417_splice | Splice Site (SNP) | VAF 50/181 reads (28%) | catalogued as rs759703432, COSV101258212; called by muse, mutect2, varscan2
- APOB | c.2802G>T p.K934N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99268164; called by muse, mutect2, varscan2
- AQP9 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs375430625, COSV54968269; called by muse, mutect2, varscan2
- ARPP21 | c.767A>T p.N256I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99493387; called by muse, mutect2, varscan2
- ASH1L | c.6610G>T p.D2204Y (on ENST00000368346 / NM_001366177.2; = p.D2199Y on NM_018489.3) | Missense Mutation (SNP) | VAF 58/253 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV100853607; called by muse, mutect2, varscan2
- ATP11B | c.2551G>C p.D851H | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018135; called by muse, mutect2, varscan2
- AURKB | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100298905; called by muse, varscan2
- BLMH | c.752T>A p.L251* | Nonsense Mutation (SNP) | VAF 40/174 reads (23%) | catalogued as COSV99913233; called by muse, mutect2, varscan2
- CCDC14 | c.1832C>T p.S611F (on ENST00000488653; = p.S563F on NM_022757.5) | Missense Mutation (SNP) | VAF 81/293 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59948046; called by muse, mutect2, varscan2
- CCDC18 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100159978; called by muse, mutect2, varscan2
- CCDC180 | c.3147G>C p.Q1049H | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100827326; called by muse, mutect2, varscan2
- CCDC73 | c.40A>T p.T14S | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV100068352; called by muse, mutect2, varscan2
- CDC5L | c.2119G>T p.A707S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV101015212; called by muse, mutect2, varscan2
- CFAP206 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.547); catalogued as rs1252914473, COSV99740148; called by muse, mutect2, varscan2
- CHL1 | c.1406G>C p.R469T (on ENST00000397491 / NM_001253387.1; = p.R485T on NM_006614.4) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.052); catalogued as COSV99852370; called by muse, mutect2, varscan2
- CHN1 | c.1184G>C p.R395P | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55036807, COSV99789465; called by muse, varscan2
- CHST10 | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99959271; called by muse, mutect2, varscan2
- CHTF8 | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774439830, COSV99544760; called by muse, mutect2, varscan2
- CNTNAP2 | c.188C>A p.A63D | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1286172885, COSV100673034, COSV62170689; called by muse, mutect2, varscan2
- CRACD | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs370003322; called by muse, mutect2, varscan2
- CRYZ | c.754A>T p.I252F | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV100558720; called by muse, mutect2, varscan2
- CSMD3 | c.11104A>G p.T3702A (on ENST00000297405 / NM_001363185.1; = p.T3533A on NM_052900.3) | Missense Mutation (SNP) | VAF 147/438 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99848015; called by muse, mutect2, varscan2
- CSMD3 | c.10402G>A p.A3468T (on ENST00000297405 / NM_001363185.1; = p.A3299T on NM_052900.3) | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.054); catalogued as COSV99848017, COSV99848047; called by muse, mutect2, varscan2
- CSMD3 | c.5980G>T p.D1994Y (on ENST00000297405 / NM_001363185.1; = p.D1890Y on NM_052900.3) | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs1297430611, COSV99836995, COSV99848019; called by muse, mutect2, varscan2
- CST7 | c.126A>G p.I42M | Missense Mutation (SNP) | VAF 107/435 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.854); catalogued as COSV100962029; called by muse, mutect2, varscan2
- CTTNBP2 | c.2896+2T>G p.X966_splice | Splice Site (SNP) | VAF 30/145 reads (21%) | catalogued as COSV99354886; called by muse, mutect2, varscan2
- CUX1 | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 37/188 reads (20%) | catalogued as COSV99473164; called by muse, mutect2, varscan2
- CZIB | c.257A>T p.Y86F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as COSV99598353; called by muse, mutect2, varscan2
- ENC1 | c.378G>T p.M126I | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV100188258; called by muse, mutect2, varscan2
- EPB41L2 | c.757C>G p.L253V | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100441421; called by muse, mutect2, varscan2
- EPHA10 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV57621228; called by muse, mutect2, varscan2
- ERBIN | c.3868C>G p.L1290V (on ENST00000284037 / NM_001253697.2; = p.L1249V on NM_018695.4) | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99397850; called by muse, mutect2, varscan2
- FAM135B | c.4067C>T p.A1356V | Missense Mutation (SNP) | VAF 104/685 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99427780; called by muse, mutect2, varscan2
- FAM135B | c.3743G>C p.G1248A | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99427785; called by muse, mutect2, varscan2
- FAM135B | c.1360T>A p.L454I | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99427787; called by muse, mutect2, varscan2
- FAM160B1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100985597; called by muse, mutect2, varscan2
- GALNT17 | c.1705C>A p.L569M | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100356295, COSV100356471; called by muse, mutect2, varscan2
- GID8 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99824207; called by muse, mutect2, varscan2
- HCN1 | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100298680, COSV57505727; called by muse, mutect2, varscan2
- HEATR4 | c.1188T>A p.S396R | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV100620623; called by muse, mutect2, varscan2
- HELZ | c.1214G>T p.R405L | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV100699070; called by muse, mutect2, varscan2
- HERC1 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101496920; called by muse, mutect2, varscan2
- HYDIN | c.14112+2T>A p.X4704_splice | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as COSV101125072, COSV101125226; called by muse, mutect2, varscan2
- IGKV1D-43 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 58/274 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748741511; called by muse, varscan2
- IL6ST | c.1371G>T p.W457C | Missense Mutation (SNP) | VAF 50/397 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61141543; called by muse, mutect2, varscan2
- INPP4B | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV99526866; called by muse, mutect2, varscan2
- INTS10 | c.1771G>C p.V591L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV101208745; called by muse, mutect2, varscan2
- INTS12 | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 81/340 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV100415934; called by muse, mutect2, varscan2
- KDR | c.1198del p.T401Pfs*28 | Frame Shift Del (DEL) | VAF 34/164 reads (21%) | catalogued as COSV55760332; called by mutect2, pindel, varscan2
- KLF7 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100518938, COSV100519408; called by muse, mutect2, varscan2
- KLHL14 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 77/257 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100839318; called by muse, mutect2, varscan2
- KMT2C | c.5094A>T p.R1698S | Missense Mutation (SNP) | VAF 151/504 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100076608; called by muse, mutect2, varscan2
- L2HGDH | c.763G>C p.V255L | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.074); catalogued as COSV99910573; called by muse, mutect2, varscan2
- LRFN5 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985494; called by muse, mutect2, varscan2
- LRRC4B | c.2051G>T p.G684V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.05); catalogued as COSV100976055; called by muse, mutect2, varscan2
- MAP3K4 | c.3616A>T p.S1206C | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV100815691; called by muse, mutect2, varscan2
- MED12L | c.4053C>G p.N1351K | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV99854792; called by muse, mutect2, varscan2
- MFN1 | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as COSV99764717; called by muse, mutect2, varscan2
- MIA3 | c.3026A>G p.N1009S | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100719536; called by muse, mutect2, varscan2
- MOGAT3 | c.1025A>T p.*342Lext*15 | Nonstop Mutation (SNP) | VAF 31/180 reads (17%) | catalogued as COSV99777336; called by muse, mutect2, varscan2
- MRGPRX2 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs775963748, COSV100316849; called by muse, mutect2, varscan2
- MROH7 | c.2101G>T p.A701S | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs554316180, COSV100274068, COSV59867868; called by muse, mutect2, varscan2
- MSLN | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.67); PolyPhen benign (0.066); catalogued as COSV53500663, COSV99558776; called by muse, mutect2, varscan2
- MTFR1 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 28/278 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV100050426; called by muse, mutect2
- MYO18B | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as COSV100125231; called by muse, mutect2, varscan2
- NAIP | c.551C>G p.A184G | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV99519481; called by muse, mutect2, varscan2
- NDST4 | c.1310G>T p.W437L | Missense Mutation (SNP) | VAF 43/182 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV99997923; called by muse, mutect2, varscan2
- NDUFS4 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV99692461; called by muse, mutect2, varscan2
- NOX3 | c.1539C>A p.N513K | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as COSV99343657; called by muse, mutect2, varscan2
- NYAP1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100278695; called by muse, mutect2, varscan2
- OR2B11 | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100276666, COSV59511318; called by muse, mutect2, varscan2
- OR2L3 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 104/587 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV100741975, COSV63456806; called by muse, mutect2, varscan2
- OR4C12 | c.92T>G p.V31G | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV58859853; called by muse, mutect2, varscan2
- OR52K2 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.661); catalogued as COSV100355855, COSV57835878; called by muse, mutect2, varscan2
- OR5J2 | c.809A>C p.Q270P | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs762704004, COSV100399248; called by muse, mutect2, varscan2
- OR5L2 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 86/350 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV101004326, COSV101004417; called by muse, mutect2, varscan2
- PCDHA12 | c.1919C>T p.A640V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.036); catalogued as rs782042077, COSV99169753; called by muse, mutect2, varscan2
- PCDHAC1 | c.598C>A p.L200M | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV99169754; called by muse, mutect2, varscan2
- PCLO | c.9920T>C p.L3307P | Missense Mutation (SNP) | VAF 50/237 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100437926; called by muse, mutect2, varscan2
- PGM5 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 104/412 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV101123567; called by muse, varscan2
- PIKFYVE | c.1472C>G p.S491C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs780466702, COSV100011470; called by muse, mutect2
- PNLIPRP1 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100724529; called by muse, mutect2, varscan2
- PROX1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54781632, COSV99800227; called by muse, mutect2, varscan2
- PTPN14 | c.1855C>G p.Q619E | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.93); catalogued as COSV100872943; called by muse, mutect2, varscan2
- PZP | c.3323C>A p.S1108Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99739507; called by muse, mutect2, varscan2
- RAD18 | c.1043G>T p.S348I | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV99368827; called by muse, mutect2, varscan2
- RCAN2 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760268134, COSV100150493; called by muse, mutect2, varscan2
- RLF | c.2293A>G p.K765E | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.095); catalogued as COSV101035706; called by muse, mutect2, varscan2
- RYR2 | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV100772927; called by muse, mutect2, varscan2
- SLC2A13 | c.1262G>C p.R421P | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55115677, COSV99787166; called by muse, mutect2, varscan2
- SLC9B2 | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 57/221 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100294366; called by muse, mutect2, varscan2
- SLITRK3 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99580204; called by muse, mutect2, varscan2
- SMARCAD1 | c.2341del p.M781Wfs*25 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as COSV100759040; called by mutect2, pindel, varscan2
- SMCO3 | c.13G>T p.D5Y | Missense Mutation (SNP) | VAF 36/229 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99660883; called by muse, mutect2, varscan2
- SMR3A | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV99895850; called by muse, mutect2, varscan2
- SORBS2 | c.1984C>A p.P662T | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99512847; called by muse, mutect2, varscan2
- SORCS3 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.061); catalogued as COSV100865663; called by muse, mutect2, varscan2
- SPTBN2 | c.4799C>T p.A1600V | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.534); catalogued as rs1192146398, COSV100020525; called by muse, mutect2, varscan2
- STAMBP | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780714201, COSV59897518; called by muse, mutect2, varscan2
- STK33 | c.1248G>T p.K416N | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100174533; called by muse, mutect2, varscan2
- STOML2 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.866); catalogued as COSV99956965; called by muse, mutect2
- SUN3 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99814391; called by muse, mutect2, varscan2
- TAC3 | c.106C>A p.R36S | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100269933; called by muse, mutect2, varscan2
- TAP2 | c.1796-1G>C p.X599_splice | Splice Site (SNP) | VAF 13/76 reads (17%) | catalogued as rs779656950, COSV100886955; called by muse, mutect2, varscan2
- TENT5D | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV100382987; called by muse, mutect2, varscan2
- TEX43 | c.365G>A p.S122N | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs772582869, COSV100847486; called by muse, mutect2, varscan2
- THSD1 | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs763406181, COSV51631930, COSV99319089; called by muse, mutect2, varscan2
- TMEM132D | c.1421C>A p.S474* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV101396633, COSV101399631, COSV70602045; called by muse, mutect2, varscan2
- TMEM135 | c.385A>T p.M129L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100450232; called by muse, mutect2, varscan2
- TMEM86A | c.555_557del p.F186del | In Frame Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs1351258199; called by pindel, varscan2
- TOX4 | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52968880, COSV99398626; called by muse, mutect2
- TRIM17 | c.971A>G p.E324G | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV99489018; called by muse, mutect2, varscan2
- TTC37 | c.2629A>G p.I877V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.264); catalogued as rs748433970, COSV100706905; called by muse, mutect2, varscan2
- TTN | c.60947C>G p.P20316R (on ENST00000591111; = p.P12892R on NM_003319.4) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | PolyPhen probably damaging (1); catalogued as COSV100618113, COSV100630490; called by muse, mutect2, varscan2
- TTN | c.19856G>C p.R6619T (on ENST00000591111; = p.R5692T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | PolyPhen possibly damaging (0.736); catalogued as COSV100630491; called by muse, mutect2, varscan2
- UBE2J1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as COSV101470293; called by muse, mutect2, varscan2
- VILL | c.250C>A p.Q84K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99379287; called by muse, mutect2, varscan2
- VPS13A | c.7142G>T p.R2381L | Missense Mutation (SNP) | VAF 76/177 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.495); catalogued as rs200068581, COSV100653550; called by muse, mutect2, varscan2
- VWA3B | c.1771A>T p.K591* | Nonsense Mutation (SNP) | VAF 33/141 reads (23%) | catalogued as COSV101291525; called by muse, mutect2, varscan2
- YTHDC2 | c.3553G>T p.E1185* | Nonsense Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99363893; called by muse, mutect2, varscan2
- ZFPM1 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778641671, COSV100128755; called by muse, mutect2
- ZNF14 | c.1776T>A p.C592* | Nonsense Mutation (SNP) | VAF 52/133 reads (39%) | catalogued as COSV100694141; called by muse, mutect2, varscan2
- ZNF184 | c.203-1G>A p.X68_splice | Splice Site (SNP) | VAF 60/190 reads (32%) | catalogued as COSV99280085; called by muse, mutect2, varscan2
- ZNF451 | c.2648G>T p.R883L | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV100675128, COSV62596962; called by muse, mutect2, varscan2
- ZNF75D | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100883533, COSV100883696; called by muse, mutect2, varscan2
- C8orf34 | c.851del p.L284Qfs*31 | Frame Shift Del (DEL) | VAF 31/175 reads (18%) | called by mutect2, pindel, varscan2
- DLC1 | c.3145_3147del p.S1049del (on ENST00000276297 / NM_001348081.2; = p.S612del on NM_006094.5) | In Frame Del (DEL) | VAF 49/192 reads (26%) | called by mutect2, pindel, varscan2
- JPH1 | c.309del p.A104Lfs*51 | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by pindel, varscan2
- JPH1 | c.303C>A p.C101* | Nonsense Mutation (SNP) | VAF 42/101 reads (42%) | called by muse, varscan2
- KCNN2 | c.1436del p.L479Wfs*14 (on ENST00000264773; = p.L691Wfs*14 on NM_021614.4) | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- MIEF2 | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NCKAP5 | c.2316del p.K772Nfs*29 | Frame Shift Del (DEL) | VAF 33/160 reads (21%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.5930dup p.Q1978Pfs*17 | Frame Shift Ins (INS) | VAF 57/136 reads (42%) | called by mutect2, pindel, varscan2
- SOX11 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2
- TRGV3 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ACTRT2 | c.444C>T p.A148= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs17845890, COSV101007677; called by muse, mutect2, varscan2
- ADCY7 | c.1035G>C p.R345= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV99576395; called by muse, mutect2, varscan2
- ADGRG5 | c.366C>T p.C122= | Silent (SNP) | VAF 48/164 reads (29%) | catalogued as rs1360057611, COSV100446514; called by muse, mutect2, varscan2
- BRCA1 | c.888A>G p.R296= | Silent (SNP) | VAF 51/200 reads (26%) | catalogued as rs1555592914, COSV100525124; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALD1 | c.1854A>G p.K618= (on ENST00000361675 / NM_033138.4; = p.K363= on NM_004342.7) | Silent (SNP) | VAF 38/116 reads (33%) | catalogued as COSV100724584; called by muse, mutect2, varscan2
- CCHCR1 | c.2238C>T p.V746= | Silent (SNP) | VAF 44/168 reads (26%) | catalogued as COSV99456325; called by muse, mutect2, varscan2
- CCL16 | c.42C>T p.I14= | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- CDH11 | c.594G>T p.V198= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as rs1006543551, COSV99219789; called by muse, mutect2, varscan2
- CIT | c.2436C>G p.L812= | Silent (SNP) | VAF 38/249 reads (15%) | catalogued as COSV99951017; called by muse, mutect2, varscan2
- COL1A1 | c.24G>T p.R8= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as rs771990895, COSV99868180; called by muse, mutect2, varscan2
- CROCC | c.1116G>A p.R372= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV65014698; called by muse, mutect2, varscan2
- CYSLTR2 | c.429C>T p.P143= | Silent (SNP) | VAF 67/241 reads (28%) | catalogued as COSV99935410; called by muse, mutect2, varscan2
- DMBT1 | c.891C>A p.V297= | Silent (SNP) | VAF 146/325 reads (45%) | catalogued as COSV100354125; called by muse, mutect2, varscan2
- DNAH5 | c.5544T>C p.N1848= | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV99454305; called by muse, mutect2, varscan2
- DZIP3 | c.2913G>C p.V971= | Silent (SNP) | VAF 127/582 reads (22%) | catalogued as COSV100848093; called by muse, mutect2, varscan2
- FBXO40 | c.21C>A p.S7= | Silent (SNP) | VAF 38/289 reads (13%) | catalogued as COSV100573321; called by muse, mutect2, varscan2
- FETUB | c.18C>T p.P6= | Silent (SNP) | VAF 74/530 reads (14%) | catalogued as rs968274910, COSV54005526; called by muse, mutect2
- FOXG1 | c.1257C>T p.P419= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as COSV100487080; called by muse, mutect2, varscan2
- GPR143 | c.324G>A p.T108= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1325423272, COSV101102283, COSV101102314; called by muse, mutect2, varscan2
- GPX6 | c.420G>T p.V140= | Silent (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100724918; called by muse, mutect2, varscan2
- HTR1B | c.249G>T p.P83= | Silent (SNP) | VAF 50/262 reads (19%) | catalogued as COSV100885490; called by muse, mutect2, varscan2
- IGSF3 | c.18G>C p.P6= | Silent (SNP) | VAF 21/145 reads (14%) | catalogued as rs373177032, COSV100605110; called by muse, mutect2, varscan2
- LCE1A | c.93A>C p.P31= | Silent (SNP) | VAF 48/197 reads (24%) | catalogued as rs1273795383, COSV100632153; called by muse, mutect2, varscan2
- LRRC7 | c.4500T>C p.S1500= (on ENST00000651989 / NM_001370785.2; = p.S1420= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 32/191 reads (17%) | catalogued as COSV99229912; called by muse, mutect2, varscan2
- MUC5AC | c.15618C>T p.G5206= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100611601; called by muse, mutect2, varscan2
- NOSTRIN | c.621C>T p.N207= (on ENST00000317647 / NM_001039724.4; = p.N129= on NM_052946.3) | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100474100; called by muse, mutect2, varscan2
- NRXN3 | c.1698C>T p.V566= (on ENST00000557594 / NM_001272020.2; = p.V990= on NM_004796.6) | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV55317112; called by muse, mutect2, varscan2
- NSUN3 | c.4C>T p.L2= | Silent (SNP) | VAF 63/278 reads (23%) | catalogued as COSV100113479; called by muse, varscan2
- NUP62 | c.423G>A p.V141= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV100352363; called by muse, mutect2
- PAPPA2 | c.2829G>A p.T943= | Silent (SNP) | VAF 53/220 reads (24%) | catalogued as rs376986324, COSV100868664; called by muse, mutect2, varscan2
- PCDH17 | c.1737C>T p.N579= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV64972042; called by muse, mutect2, varscan2
- PCDHA7 | c.201G>T p.V67= | Silent (SNP) | VAF 58/363 reads (16%) | catalogued as rs139714335, COSV100971837; called by muse, mutect2, varscan2
- PCDHGA2 | c.2109C>T p.V703= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as COSV99547210; called by muse, mutect2, varscan2
- PCDHGB5 | c.6G>A p.G2= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV53960425; called by muse, mutect2, varscan2
- PLCE1 | c.507G>A p.Q169= | Silent (SNP) | VAF 67/152 reads (44%) | catalogued as COSV99597289; called by muse, mutect2, varscan2
- PTPRZ1 | c.6723C>T p.H2241= | Silent (SNP) | VAF 57/220 reads (26%) | catalogued as COSV101099594, COSV66440492; called by muse, mutect2, varscan2
- REG3G | c.387T>C p.N129= | Silent (SNP) | VAF 34/218 reads (16%) | catalogued as rs774433012, COSV99709726; called by muse, mutect2, varscan2
- RYR2 | c.4557A>T p.T1519= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100772929; called by muse, mutect2, varscan2
- SCN1A | c.5400G>A p.L1800= (on ENST00000303395 / NM_001202435.3; = p.L1789= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/215 reads (16%) | catalogued as COSV100322495, COSV57658667; called by muse, mutect2, varscan2
- SEPTIN14 | c.900C>T p.T300= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as COSV101193437; called by muse, mutect2, varscan2
- SHANK3 | c.1554G>A p.V518= | Silent (SNP) | VAF 6/48 reads (13%) | called by mutect2, varscan2
- SLC12A7 | c.441G>A p.V147= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV99370591; called by muse, varscan2
- SLITRK3 | c.2901C>T p.L967= | Silent (SNP) | VAF 86/375 reads (23%) | catalogued as rs757838414, COSV53851275, COSV53854620, COSV99580203; called by muse, mutect2, varscan2
- SPATS2 | c.114G>C p.A38= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100423745; called by muse, mutect2, varscan2
- SPEG | c.855C>T p.D285= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100405685; called by muse, mutect2, varscan2
- TIPARP | c.1068A>T p.G356= | Silent (SNP) | VAF 82/336 reads (24%) | catalogued as COSV99904010; called by muse, mutect2, varscan2
- TLN1 | c.2385T>A p.A795= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as COSV100148266; called by muse, mutect2, varscan2
- TMEM98 | c.540G>A p.T180= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as rs759666021, COSV55583084; called by muse, mutect2, varscan2
- TRERF1 | c.1683G>T p.P561= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100551717; called by muse, mutect2, varscan2
- TRIM22 | c.1467C>T p.V489= | Silent (SNP) | VAF 57/201 reads (28%) | catalogued as COSV101181520; called by muse, mutect2, varscan2
- TTLL5 | c.2970C>T p.P990= | Silent (SNP) | VAF 37/181 reads (20%) | catalogued as rs140291071, COSV100091647; called by muse, mutect2, varscan2
- URM1 | c.60C>T p.D20= | Silent (SNP) | VAF 19/183 reads (10%) | catalogued as rs760936676, COSV65717314; called by muse, mutect2, varscan2
- USP40 | c.483G>T p.L161= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99297195; called by muse, mutect2, varscan2
- ZNF318 | c.4950G>T p.L1650= | Silent (SNP) | VAF 83/300 reads (28%) | catalogued as COSV100546531; called by muse, mutect2, varscan2
- ZNF483 | c.246A>G p.R82= | Silent (SNP) | VAF 70/153 reads (46%) | catalogued as COSV100493130; called by muse, mutect2, varscan2
- ZNF516 | c.381G>T p.L127= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV101487373; called by muse, mutect2, varscan2
- ZSCAN5A | c.1347C>T p.F449= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99570707; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504366 del TGTT | 5'Flank (DEL) | VAF 9/69 reads (13%) | catalogued as rs752466660; called by mutect2, pindel, varscan2
- LEKR1 | c.*416C>T | 3'UTR (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100739333; called by muse, mutect2, varscan2
- SNORD115-21 | n.60C>G | RNA (SNP) | VAF 111/376 reads (30%) | called by muse, mutect2, varscan2
- SNORD115-43 | n.57T>A | RNA (SNP) | VAF 115/424 reads (27%) | called by muse, mutect2, varscan2
- STK25 | c.*1A>G | 3'UTR (SNP) | VAF 22/76 reads (29%) | catalogued as COSV99885608; called by muse, mutect2, varscan2
- TRAC | c.*425A>T | 3'UTR (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
